Gene-level copy-number profile of tumor specimen TCGA-36-2534-01A from TCGA case TCGA-36-2534, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.9 years (26,621 days).
Specimen TCGA-36-2534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fc832eea-a988-4f59-bf1c-3df2b37f3e32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2534-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fa95e62d-c6ad-4c34-b244-6e9dd0b8d74f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 16,812; copy number 2: 33,323; copy number 3: 7,814; copy number 4: 1,009; copy number 5: 765; copy number 6: 91; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2534-01A-01D-1043-01): tumor purity 0.91, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:18,513,115–18,545,651, 2 genes (within-gene range 0–1): AL450384.2, AL450384.1.
- chr16:68,358,327–68,448,508, 1 gene (within-gene range 0–1): SMPD3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 857 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:152,449,272–176,867,838, 323 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:46,243,548–46,244,215, 1 gene, copy number 5: AC104072.1.
- chr5:155,491,336–155,493,598, 1 gene, copy number 5: AC008725.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.
- chr8:110,766,863–145,066,685, 531 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,788. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
